Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5709, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5709-01A (Primary Tumor).

KIDNEY, RIGHT, RADICAL NEPHRECTOMY:

B. FUHRMAN'S NUCLEAR GRADE IS 3 OF 4.

C. THE GREATEST DIAMETER OF THE NEOPLASM IS 5 CM.

D. THE NEOPLASM IS SEEN FOCALLY INFILTRATING INTO, BUT NOT THROUGH, THE RENAL CAPSULE (SEE COMMENT).

E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.

F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.

G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.

H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.

1. THE ADRENAL GLAND IS UNREMARKABLE.

J. TNM STAGE: pT3a Nx Mx.

K. TNM HISTOLOGIC GRADE = G3.

The tumor is seen to be focally infiltrating into the renal capsule, but not through it. This is interpreted as constituting a T stage 3A tumor. Clinical and radiological correlation is suggested.

SYNOPTIC - PRIMARY KIDNEY/RENAL PELVIS/URETER TUMORS

- A. Side: 1
- B. Location: 1
- C. Procedure: 3
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 5 cm
- E. Type of malignant neoplasm: 1/5
- F. Histologic grade
- G. Non-neoplastic and other conditions: # / # / # / #
- H. Margins of resection: 2
- I. Mitotic activity: # per 10 high power fields
- J. Angiolymphatic invasion
- K. Number of positive lymph nodes: N/A
- L. Total number of lymph nodes examined: N/A
- M. Extracapsular spread of lymph node metastases: N/A
- N. Adrenal gland:
- O. TNM stage: T 3a N x M x
1. Right
2. Left
1. Kidney (parenchyma - cortex/medulla)
2. Kidney (pelvis)
1. Partial nephrectomy
2. Simple nephrectomy
3. Radical nephrectomy
- Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 5 cm
- Type of malignant neoplasm: 1/5
- Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)
- Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)
- Renal cell carcinoma, chromophobe cell type
- Renal cell carcinoma, oncocytic
- Renal cell carcinoma, sarcomatoid
- Collecting duct carcinoma
- Urothelial carcinoma, TCCa (non-invasive)
- Urothelial carcinoma, TCCa (invasive ± in-situ)
- Urothelial carcinoma, squamous carcinoma
- Urothelial carcinoma, adenocarcinoma
- Histologic grade
- Fuhrman grade (for RCC; grades 1-4): 3
- Ash grade (grade 1-4): N/A
- WHO grade (grade 1-3): N/A (for TCCa)
- F4. [REDACTED]
1. LMP 2. LG 3. HG
- F5 Other malignant neoplasms (grades 1-3): N/A
- Non-neoplastic and other conditions: # / # / # / #
- Glomerulopathy
- Interstitial nephritis
- Pyelonephritis
- Nephrolithiasis
- Papillary necrosis
- Chronic parenchymal disease
- Other
- Margins of resection: 2
- Mitotic activity: # per 10 high power fields
- Angiolymphatic invasion
- J1. Macroscopic (e.g., renal vein thrombus): 2
- J2. Microscopic: 2
- Number of positive lymph nodes: N/A
- Total number of lymph nodes examined: N/A
- Extracapsular spread of lymph node metastases: N/A
1. Yes 2. No
- Adrenal gland:
- N1. Present 1
- N2. Involvement by renal neoplasm: 2
- N3. Other adrenal pathology: 2
- TNM stage: T 3a N x M x
1. Positive 2. Negative
1. Positive 2. Negative
1. Positive 2. Negative
1. Positive 2. Negative
1. Yes 2. No 3. Not Applicable
1. Yes 2. No 3. Not applicable

Source: NCI Genomic Data Commons file a500889d-f727-48a5-8eb0-b23221a1ce16 (TCGA-B0-5709.9783378C-0053-4D4F-ACB0-B55C1E6C8849.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).